Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABDN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABDN-TTP1-A (Primary Tumor).

[page 1 of 19]
2 blocks of core material

Department of Pathology and Laboratory Medicine

SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #

Med. Rec. #

DOB:

Gender:

Physician(s):

Client:

Location:

Acct

Copy To:

Taken:

Received:

Reported:

+6
+6
+17

Final Diagnosis

"Liver", CT guided biopsy- Hepatoid adenocarcinoma. See note.

NOTE: The carcinoma demonstrates a trabecular to solid architecture separated by septa with thin blood vessels. The tumor cells are medium sized cells with a moderate degree of clear to focally eosinophilic cytoplasm which has occasional hyaline globules. Mucicarmine stain is focally positive. Nuclei are generally round and hyperchromatic with occasional nuclear vacuoles, modest anisonucleosis and they lack nucleoli. Necrosis is present and mitotic activity is easily found. No hepatic tissue is noted. A panel of immunostains was performed (see table below).

ANTIBODY	RESULT
Hepatocyte (HepPar1)	Negative
Arginase 1	Very focal positive (5%)
MOC31	Positive
Glipican-3	Positive
AFP	Positive
SALL4	Positive
pCEA	Positive for glandular pattern (no definitive canalicular pattern)
CDX2	Positive

(N)

Abdominal CT scan report indicates the presence of multiple hepatic masses without mention of tumor elsewhere in the abdomen. The laboratory information system indicates that the patient has a serum alpha-fetoprotein of 18,803ng/ml. The histologic and immunophenotypic features of this case are those of a hepatoid adenocarcinoma, considered a histologic subset of AFP producing carcinomas. These tumors frequently are associated with an elevated (often strikingly so) serum AFP. Most commonly they arise in the stomach where typically they are also associated with a superficial component of usual adenocarcinoma. They frequently metastasize to the liver and occasionally present as hepatic malignancy. Hepatoid adenocarcinomas may also arise at other

[page 2 of 19]
SURGICAL PATHOLOGY REPORT

sites including the esophagus (associated with Barrett esophagus) and rarely other GI and extra-GI sites.

Re-review of the abdominal CT scan suggested that the wall of the proximal esophagus appeared thickened and was suspicious for malignancy. This case was discussed with [REDACTED] as well as [REDACTED]. An upper endoscopy was performed and [REDACTED] indicated that a mass (4cm) was present in the primarily in the distal esophagus, but also (~1cm) in the proximal stomach. Biopsies were obtained (directed to an outside lab for insurance purposes) and verbal report from [REDACTED] indicates that adenocarcinoma was found.

REFERENCES

1. Liu X et al. Analysis of clinicopathologic features and prognostic factors in hepatoid adenocarcinoma of the stomach. Am J Surg Pathol 2010;34:1465-1471
2. Zhang J-F et al. Clinicopathologic and prognostic features of hepatoid adenocarcinoma of stomach. Chin Med 2011;124:1470-1476.
3. Kinjo T et al. Histologic and Immunohistochemical analyses of alpha-fetoprotein-producing cancer of the stomach. Am J Surg Pathol 2012;36:56-65.
4. Chiba N et al. AFP-Producing hepatoid adenocarcinoma in association with Barrett's esophagus with multiple liver metastasis responding to paclitaxel/CDDP: a case report. Anticancer research 2005;25:2965-2968.
5. Kuroda N et al. Combined tubular adenocarcinoma and hepatoid adenocarcinoma arising in Barrett esophagus. Ann Diagnostic Pathol 2011;15:450-453.

Specimen(s) Submitted

"Liver biopsy"

+0

History

Mass on CT [REDACTED] (mult. liver lesions); no CA hx.

Gross Description

Received in formalin, designated as "liver biopsy" and labeled with patient's name [REDACTED]. It consists of 3 white-tan, cylindrical core biopsies measuring 1.2, 1.5 and 1.6 cm in length by 0.1-cm in diameter. The specimen is entirely submitted in one block.

Subsequently the block is divided into two equal portions [REDACTED] designated as "a" and "b".

[page 3 of 19]
Patient: [REDACTED]

DOB: [REDACTED]

Accession Number: [REDACTED]

*****ADDENDUM REPORT*****

***** GASTROESOPHAGEAL TUMOR PREDICTIVE STUDY *****

DIAGNOSIS:

ADENOCARCINOMA, DISTAL, PROXYMAL BODY ESOPHAGEAL MASS (A);

OVER- EXPRESSION OF HER-2/neu Protein

AMPLIFIED HER-2/neu by FISH (See comment)

IHC RESULT: *Over-Expression of HER-2/neu Protein (3+)

**Reference Range: Negative or Not Over-Expressed (0/1+); Equivocal (2+); Over-Expressed (3+)*

FISH Results:

The HER2:CEN17 ratio is 6.6

Average HER-2 signal per nucleus is 11.87

Average D17Z1 signals per nucleus is 1.8

**The HercepTest™ is a semi-quantitative immunohistochemical assay for determination of HER2 protein (c-erbB-2 oncoprotein) overexpression in breast cancer tissues routinely processed for histologic evaluation and in formalin-fixed, paraffin-embedded cancer tissue from patients with metastatic gastric or gastroesophageal junction adenocarcinoma. HercepTest™ is an aid in the assessment of patients for whom treatment with humanized monoclonal antibody to HER2 protein, Herceptin® (trastuzumab), is being considered. Decision regarding Herceptin® treatment should be made within the context of the patient's clinical history. The adequacy of HER2 staining is verified by appropriate positive and negative controls. Their performance characteristics have been validated by OncoMetrix, Memphis, TN. They have not been reviewed by the FDA. The FDA has deemed that such approval is unwarranted. These assays are for clinical use and should not be viewed as experimental or for "research use only".*

The FISH test is performed using HER2 FISH pharm DX™ Kit (DAKO) containing probes for HER2 gene at 17q12 and a chromosome 17 control probe CEN17 (DAKO) on 4µ sections cut from formalin fixed paraffin embedded tissue. The probe mix is hybridized to areas preselected by a Pathologist using the Hand E slides. Two technologists count signals from 20 nuclei each for a total of 40 cells from invasive tumor. The results are reported as the average ratio of HER2 signals as compared to the CEN17 signals. A HER2:CEN17 ratio of >2.2 is consistent with HER2 amplification, a HER2:CEN17 ratio of 1.8 to 2.2 is considered to be equivocal and a HER2:CEN17 ratio of <1.8 is not amplified. If the ratio is between 1.8 and 2.2, additional 40 nuclei are counted. This test was developed and its performance characteristics determined by the Cytogenetics laboratory at OncoMetrix. This test has been approved by FDA for evaluating the amplification status of HER2 in gastroesophageal cancer. This test does not diagnose or screen for gastroesophageal cancer. The results from the tested tissue do not represent the entire neoplastic cell population from this individual.

[page 4 of 19]
[REDACTED]

[REDACTED]

[REDACTED]

+0

Patient:

[REDACTED]

DOB:

[REDACTED]

Accession Number:

[REDACTED]

[REDACTED]

APPENDUM REPORT *****

[REDACTED]

[REDACTED]

[REDACTED]

[page 5 of 19]
Final, Corrected Report

S
A
M
P
L
E

Specimen ID: [REDACTED]
Date of Report: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Source: LIVER BX
Clinical Information: [REDACTED]

+11
+6
+7

IMMUNOHISTOCHEMISTRY

RESULTS

Antibody	Clone	Description	Results
Hepatocyte	OCH1 E5	Hepatocyte antigen	Stain Only
MOC31	MOC31	Epithelial cells; adenocarcinoma subset	Stain Only
Arginase-1	Polytypic	hepatocytes; hepatocellular carcinoma	Stain Only
Additional markers			
[REDACTED] +10			
AFP	Polyclonal	Alpha Fetoprotein; hepatocellular and germ cell tumors	Stain Only
Glypican-3	1G12	GPC3, Hepatocellular Carcinoma, Germ Cell Tumors	Stain Only

Report was corrected due to clerical error on patient last name.

[REDACTED]

[REDACTED]

[REDACTED]

[page 6 of 19]
Accession Number:
Date of Service (Collection):
Date Received:
MR/Chart:

+13
+14

***** ADDENDUM REPORT *****

CLINICAL HISTORY: Abnormal CT.
CLINICAL IMPRESSION: Rule out cancer. A tumor found in the lower third of the esophagus. Multiple biopsies taken. Normal duodenum.

GROSS DESCRIPTION:

- A. Received in zinc formalin are five fragments of soft tissue measuring 0.7 cm x 0.6 cm x 0.2 cm in aggregate. Totally submitted. Sections: AI-5.

FINAL DIAGNOSIS:

- A. DISTAL, PROXIMAL BODY ESOPHAGEAL MASS

Adenocarcinoma, moderately differentiated.

Barrett's mucosa not identified (Alcian blue stain negative for goblet cells).

Silver stain negative for H. pylori.

HER-2 neu studies pending; results to be issued in an addendum.

NOTE: Adenocarcinoma is present in both sections of gastric cardia as well as squamous esophageal tissue. The malignant nature of this lesion was independently confirmed by a second fellowship-trained gastrointestinal pathologist.

Please see photomicrograph(s) on page 2.

[page 7 of 19]
*****ADDENDUM REPORT*****

Proximal esophagus, distal esophagus, gastric body

[page 8 of 19]
Name: [REDACTED] Plan: [REDACTED]
Birth Date: [REDACTED]
Sex: Male Version: N/A
Patient ID: [REDACTED]

Date/Time of Visit: [REDACTED] +11

Collection Date: [REDACTED] Status: Approved Requesting Provider: [REDACTED]

+0

CT Abd/Pelvis w/Contrast

FINAL REPORT

CAT SCAN

CT ABD PEL W CONTRST (NON OS) [REDACTED]

+0

COMMENTS:

Clinical Indication: Abdominal mass, periumbilical
Comparison: None available.
Spiral CT images were obtained through the abdomen and pelvis utilizing intravenous and oral contrast administration. 100 cc of Omnipaque-350 contrast was administered. Mild atelectasis/scarring is present at the lung bases. There is mild elevation of the right hemidiaphragm.
The liver is enlarged. Multiple hepatic masses are present. These demonstrate heterogeneous enhancement and appear more necrotic centrally. The largest include the following: A mass near the junction of the right and left lobes anteriorly measures 9.6 x 7.7 cm on image 23. A mass in the right lobe posteriorly demonstrating extensive calcification measures 15.6 x 14.2 cm on image 27. A mass in the lateral segment of the left lobe measures 18.8 x 15.3 cm on image 40. A mass in the right lobe inferiorly measures 15.0 x 1.1 cm.
The gallbladder is not well visualized. No significant biliary distention is demonstrated. The spleen, pancreas, kidneys and adrenal glands demonstrate no significant abnormality. The abdominal aorta is not aneurysmal. The IVC is mildly prominent in caliber inferiorly and is narrowed as it passes through the liver. This suggests mild hemodynamic compromise of the IVC as it passes through the liver.

The urinary bladder, prostate and seminal vesicles are grossly intact. No bowel obstruction is demonstrated. The appendix is not identified. No free fluid or adenopathy is demonstrated. There are degenerative changes of the spine.

IMPRESSION:

Multiple hepatic masses are present suggesting metastatic disease. One of the masses demonstrates extensive calcification as can be seen in mucinous adenocarcinoma. Nonvisualization of the gallbladder likely related to compression by hepatic masses.
There is evidence of mild hemodynamic compromise of the IVC as it passes through the liver.
A preliminary report was given to facility personnel to be communicated to the referring physician's office.

[page 9 of 19]
Name:

Plat:

Birth Date:

Sex: Male

Version: N/A

Centricity Patient ID:

Date/Time of Visit:

+11

Collection Date:

Status: Approved

Requesting Provider:

+0

[page 10 of 19]
Results

CT CHEST ABD PEL W (OS/NON)

PACS Images

Show images for CT CHEST ABD PEL W (OS/NON)

Result Information

Status: Final result (Collected: +104

Radiology Conversion

+1676

NARRATIVE: FINAL REPORT

ECT
CT CHEST ABD PEL W (OS/NON) +104

COMMENTS: Clinical History: Liver carcinoma.

Procedure: CAT scan of the chest, abdomen, and pelvis was performed after administration of oral contrast and intravenous administration of 100 cc of Omnipaque 350.

Comparison: PET/CT +16

Findings:

Chest:

Right chest wall porta catheter with its tip within the inferior SVC. No axillary, hilar, or mediastinal lymphadenopathy.

The heart is normal in size. No pericardial or pleural effusions.

Scarring versus atelectasis within the right lower lobe. Subtle small groundglass opacities within the right upper lobe image 20 series 5 which are indeterminant.

Degenerates changes of the spine

Impression-

1. New minimal groundglass opacities within the right upper lobe which are indeterminate. Differential diagnosis include inflammatory infectious or much less likely a neoplastic process.

Abdomen and pelvis:

There are 4 masses within the liver. One mass within the inferior aspect of the left lower lobe measuring up to 8.2 x 8.5 cm previously measuring up to 14.5 x 19.5 cm. The adjacent lesion within the junction of the left and right lobe of the liver measures 5.9 x 6.8 cm previously measuring approximately 14.0 x 13.0 cm. Questionable 2.1 cm hemangioma within the left lobe of the liver image 37 series 3. There is a 5.6 x 4.8 cm lesion

[page 11 of 19]
[REDACTED]

within the superior aspect of the right lobe liver previously measuring approximately 10.9 x 8.1 cm. The lesion within the right lobe measuring 12 cm which demonstrates increased density likely related to previous chemoembolization measuring 14.8 cm on today's exam.

[REDACTED]

The gallbladder pancreas and adrenal glands are unremarkable. There is mild thyromegaly unchanged. No hydronephrosis.

The bladder is unremarkable. Mild constipation. There is colonic diverticulosis without evidence of diverticulitis. No bowel obstruction. The appendix is not visualized although there are no inflammatory changes in its expected location. trace fat-containing umbilical hernia.

There are degenerative changes of the spine.

IMPRESSION:

1. Multiple liver masses which are decreased in size from the prior exam.
2. Minimal splenomegaly unchanged.
3. Colonic diverticulosis

CPT CODE:

[REDACTED]

External Result Report

External Result Report

Order Dates

	Order Date	Order Time	Performed Date	Prelim Date	Signing Date	Addendum Date
+104	[REDACTED]					+104

Signed by

Signed	Date/Time	Phone	Pager
[REDACTED]			

+104

Patient Care Timeline

No data selected in time range

IR Timeline Report

Event Log

Provider Information

CT CHEST ABD PEL W (OS/NON)

[REDACTED]

Status: Completed

[REDACTED]

[page 12 of 19]
Results

CT CHEST ABD PEL W (OS/NON)

PACS Images

Show images for CT CHEST ABD PEL W (OS/NON)

Result Information

Status: Final result (Collected

+635

Radiology Conversion

+1676

NARRATIVE: FINAL REPORT

ECT

CT CHEST ABD PEL W (OS/NON)

+635

COMMENTS: STUDY: CT of the CHEST and ABDOMEN and PELVIS after the uneventful intravenous administration of 100 cc of Omnipaque 350. Oral contrast was also used.

INDICATION: Metastatic gastric cancer

COMPARED WITH: CT of the chest, abdomen, and pelvis performed on

+550

CHEST

LUNG AND AIRWAYS: The airways appear widely patent throughout. Tiny scattered calcified granulomas. There are a few new small nonspecific groundglass nodular opacities seen along the right minor fissure within the inferior right upper lobe and superior

right middle lobe measuring up to 1 cm on image #29 of series 4. Minimal atelectasis within the right middle lobe, lingula, and lung bases.

PLEURA: No pleural effusion or pneumothorax.

VESSELS: within normal limits.

HEART: normal size. No pericardial effusion.

MEDIASTINUM AND HILA: No significant lymphadenopathy. Mild apparent distal esophageal wall thickening may be related to esophagitis.

CHEST WALL AND LOWER NECK: No significant supraclavicular or axillary lymphadenopathy. Right chest wall Infuse-a-Port in place.

ABDOMEN:

LIVER: There is a large previously chemoembolized mass within the posterior segment of the right lobe measuring 9.3 x 8.2 cm on image #18 of series 3, previously measuring 9.3 x 8.3 cm. There is a probable small additional chemoembolized stable lesion

within the medial segment of the left lobe on image #28. There are additional non-treated metastatic foci within the anterior segment of the right lobe and within the left lobe. That within the anterior segment measures 4.7 x 3.2 cm on image #11 of

series 3, previously measuring 4.8 x 3.3 cm. The lesion within the medial segment of the left lobe measures 4.9 x 4.6 cm on image #26, previously

[page 13 of 19]
measuring 4.9 x 4.6 cm. The lesion within the lateral segment of the left lobe measures 5.9 x 5 cm on image #25, previously measuring 6.1 x 5.3 cm.
BILE DUCTS: normal caliber.
GALLBLADDER: No calcified gallstones. Normal caliber wall.
PANCREAS: Atrophic.
SPLEEN: within normal limits.
ADRENALS: within normal limits.
KIDNEYS: Within normal limits. No hydronephrosis or perinephric stranding.

PELVIS:

REPRODUCTIVE ORGANS: Normal size prostate gland. Symmetric seminal vesicles.

URETERS: within normal limits.

BLADDER: within normal limits.

BOWEL: Normal caliber throughout. Small to moderate amount of stool seen throughout the colon. No significant bowel wall thickening. No discrete gastric masses are identified at this time. Diverticulosis coli without CT evidence of diverticulitis. Normal appendix. No enlarged mesenteric lymph nodes.
PERITONEUM: no ascites or free air, no fluid collection.
VESSELS: Atherosclerotic changes.
RETROPERITONEUM: No enlarged retroperitoneal or pelvic nodes.
ABDOMINAL WALL: within normal limits.
BONES: Mild degenerative changes.

IMPRESSION: 1. Findings consistent with prior granulomatous disease.
2. Nonspecific new focal ground glass nodules within the right upper and right middle lobes as discussed above. Further followup in 3 months is recommended.
3. Possible mild esophagitis.
4. Stable to slightly improved hepatic metastases as discussed above.
5. Possible mild constipation. Diverticulosis coli without CT evidence of diverticulitis.

This patient has been identified for nurse navigator assistance.

Fleischner Society Recommendations for Management of Ground Glass Nodule (GGN) and Part-Solid Nodule

1. Solitary pure ground glass nodule (GGN):

-If less/equal to 5mm: No CT follow-up required.
-If greater than 5mm: Initial follow-up at 3 months, and if persists, then annual follow-up for a minimum of 3 years (PET not recommended).

2. Solitary mixed ground glass and solid nodule:

-Initial follow-up at 3 months. If persists, and:

-If solid component is less than 5mm, then annual follow-up for minimum of 3 years.

[page 14 of 19]
[REDACTED]

-If solid component is greater/equal to 5mm, then biopsy or surgical resection.

-If greater than 10mm, consider PET.

3. Multiple subsolid GGNs:

-Pure GGN less/equal to 5mm: Follow-up at 2 years and 4 years.

-Pure GGN greater than 5mm and no dominant lesion: Initial follow-up at 3 months, and if persists, then annual follow-up for minimum of 3 years. (PET not recommended).

-Dominant nodule(s) with part-solid or solid component: Initial follow-up at 3 months, and if persists, biopsy or surgical resection, especially with solid component greater than 5mm.

(Radiology 2013 Jan; 266(1) 304-317)

CPT CODE:

[REDACTED]

External Result Report

External Result Report

Order Dates

	Order Date	Order Time	Performed Date	Prelim Date	Signing Date	Addendum Date
+635	[REDACTED]					+635

Signed by

Signed	Date/Time	Phone	Pager
[REDACTED]			

Patient Care Timeline

+635

No data selected in time range

IR Timeline Report

Event Log

Provider Information

CT CHEST ABD PEL W (OS/NON) [REDACTED]

Electronically signed by: [REDACTED] Radiology Conversion on

Status: Completed

+635

Ordering user: [REDACTED] Radiology Conversion Ordering provider: [REDACTED]

+635

[REDACTED] Printed [REDACTED]

[page 15 of 19]
Manager©

Printed: [REDACTED]

Page 2 of 3

Test Results

Name: [REDACTED]

Birth Date: [REDACTED]

Sex: Male

Patient ID: [REDACTED]

Plan: [REDACTED]

Version: N/A

Date/Time of Visit: [REDACTED] +726

Collection Date: [REDACTED]

Status: Approved

Requesting Provider: [REDACTED]

+726

CT Chest/Abd/Pelv

FINAL REPORT
FINAL REPORT

ECT
CT CHEST ABD PEL W (OS/NON) [REDACTED]

+726

COMMENTS: BA
History: With metastatic gastric neoplasm.
Comparison: Multiple prior studies most recently [REDACTED] +635
Technique:
CT of the chest, abdomen and pelvis was performed with intravenous contrast. 100 cc of Omnipaque 350 was administered intravenously.
Findings:

Stable 2 mm nodule at the left apex (4/11) there are no new or suspicious nodules.
There is no pleural effusion.
There is no pneumothorax.
The heart is normal in size. There is no thoracic aortic aneurysm.
There is no hilar, mediastinal or axillary lymphadenopathy.
There is diffuse circumferential wall thickening in the esophagus. There is marked wall thickening in the distal esophagus extending to the gastroesophageal junction. The stomach is contracted and cannot be adequately assessed. A distinct mass is not identified.
Multiple hepatic masses, stable to decreased in size. At the hepatic dome there is a 3.7 x 3.0 cm stable heterogeneous lesion. In the lateral segment of the left hepatic lobe there is a partially exophytic lesion measuring 4.9 x 5.6 cm previously 5.1 x 5.9 cm. Exophytic lesion in the medial segment of the left hepatic lobe measures 4.4 x 4.0 cm previously 4.8 x 4.3 cm. Densely calcified mass in the posterior segment of the right hepatic lobe is also unchanged. No calcified gallstones.
The pancreas is normal.
The spleen is normal.
The adrenal glands are normal.
The kidneys are normal.
There is no bowel obstruction. There are colonic there are reticular.
There is a very small fat-containing umbilical hernia.
There are stable subcentimeter pericecal iliac/gastrohepatic lymph nodes.
There are no enlarged lymph nodes in the abdomen or pelvis.
There is no free or loculated fluid.
There is no focal abnormality of the

[page 16 of 19]
Manager®

Printed: [REDACTED]

Page 3 of 3

Name: [REDACTED]

Plan: [REDACTED]

Birth Date: [REDACTED]

Version: N/A

Sex: Male

Patient ID: [REDACTED]

Date/Time of Visit: [REDACTED]

+726

Collection Date: [REDACTED]

Status: Approved

Requesting Provider: [REDACTED]

+726

urinary bladder.
The prostate and seminal vesicles are
normal.

Degenerative disease in the sacroiliac
joints.

IMPRESSION: Of the 3 hepatic lesions one
has remained stable while the
other 2 have slightly decreased in size.
No new lesions have developed.
No pulmonary nodules.
Marked diffuse wall thickening in the
distal esophagus extending to the
gastroesophageal junction of uncertain
etiology. Inflammatory or
neoplastic processes have an identical
appearance on imaging.

CPT CODE:
[REDACTED]

[page 17 of 19]
Manager©

Printed: [REDACTED]

Page 2 of 3

Name: [REDACTED]

Plan: [REDACTED]

Birth Date: [REDACTED]

Sex: Male

Version: N/A

Patient ID: [REDACTED]

Date/Time of Visit [REDACTED]

+831

Collection Date: [REDACTED]

Status: Approved

Requesting Provider: [REDACTED]

+831

CT Chest/Abd/Pelv

FINAL REPORT
FINAL REPORT

ECT

CT CHEST ABD PEL W (OS/NON) [REDACTED]

+831

COMMENTS: STUDY: CT of the CHEST and ABDOMEN and PELVIS after the uneventful intravenous administration of 100 cc of Omnipaque 350. Oral contrast was also used.
INDICATION: Metastatic gastric cancer
COMPARED WITH: CT the chest, abdomen, pelvis performed on [REDACTED]

+635

CHEST

LUNG AND AIRWAYS: The airways appear widely patent throughout. There is a stable tiny 0.3 cm left lower lobe nodule on image #46 of series 4. Stable tiny 0.2 cm subpleural left upper lobe nodule on image #30. Stable mild nodularity within the subpleural lung apices. There is no new lung nodule or mass.
PLEURA: No pleural effusion or pneumothorax.
VESSELS: within normal limits.
HEART: normal size. No pericardial effusion.
MEDIASTINUM AND HILA: No significant lymphadenopathy. Mild apparent diffuse esophageal wall thickening may related to esophagitis. Probable gastroesophageal reflux.
CHEST WALL AND LOWER NECK: No significant supraclavicular or axillary lymphadenopathy. Right chest wall Infuse-a-Port in place.

ABDOMEN:

LIVER: There is a large chemoembolized metastatic lesion within the right lobe. There is no evidence of surrounding local tumor recurrence. There are continued additional focal areas of metastases which have both increased in size and number since the previous exam. The largest lesion within the right lobe is seen superiorly measuring 4.6 x 3.7 cm on image #11 of series 3, previously measuring 3.5 x 3.5 cm. The largest lesion within the left lobe is seen within the subcapsular lateral segment measuring 6.3 x 4.9 cm on image #20, new since the previous exam. There is an additional lesion within the lateral segment measuring 5.4 x 5.4 cm on image #23, previously measuring 5.4 x 4.9 cm.
BILE DUCTS: normal caliber.

[page 18 of 19]
Manager®

Printed: [REDACTED]
Page 3 of 3

Test Results

Name: [REDACTED]
Birth Date: [REDACTED]
Sex: Male
Patient ID: [REDACTED]

Plan: [REDACTED]

Version: N/A

Date/Time of Visit: [REDACTED] +831

Collection Date: [REDACTED] Time: [REDACTED] Status: Approved Requesting Provider: [REDACTED]

+831

GALLBLADDER: No calcified gallstones.
Normal caliber wall.
PANCREAS: Mildly atrophic.
SPLEEN: within normal limits.
ADRENALS: within normal limits.
KIDNEYS: Within normal limits. No
hydronephrosis or perinephric stranding.

PELVIS:
REPRODUCTIVE ORGANS: The prostate gland
is mildly enlarged. Symmetric
seminal vesicles.
URETERS: within normal limits.
BLADDER: within normal limits.

BOWEL: Normal caliber throughout. Small
to moderate amount of stool seen
throughout the colon. No significant
bowel wall thickening. There is no
significant gastric wall thickening. No
focal nodularity. Diverticulosis
coli without CT evidence of
diverticulitis. No enlarged mesenteric
lymph nodes.
PERITONEUM: no ascites or free air, no
fluid collection.
VESSELS: Atherosclerotic changes .
RETROPERITONEUM: No enlarged
retroperitoneal or pelvic nodes.
ABDOMINAL WALL: within normal limits.
BONES: Degenerative changes. Minimal
chronic loss of height of a few of
the midthoracic vertebral bodies.

IMPRESSION: 1. Stable likely benign lung
nodularity. No new lung nodule
or mass.
2. Possible mild esophagitis. Probable
gastroesophageal reflux.
3. Increasing hepatic metastases.
4. Mildly enlarged prostate gland.
5. Possible mild constipation.
6. Diverticulosis coli without CT
evidence of diverticulitis.
7. Mild likely chronic loss of height of
a few of the midthoracic
vertebral bodies.

CPT CODE:

[page 19 of 19]
To:

ER-ABDN-TTP1-PR

SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #:

Med. Rec. #:

Client:

Taken:

DOB:

Location:

Received:

Gender:

Acct:

Reported:

Physician(s):

Copy To:

Final Diagnosis

"Liver", CT guided biopsy- Hepatoid adenocarcinoma. See note.

NOTE: The carcinoma demonstrates a trabecular to solid architecture separated by septa with thin blood vessels. The tumor cells are medium sized cells with a moderate degree of clear to focally eosinophilic cytoplasm which has occasional hyaline globules. Mucicarmine stain is focally positive. Nuclei are generally round and hyperchromatic with occasional nuclear vacuoles, modest anisonucleosis and they lack nucleoli. Necrosis is present and mitotic activity is easily found. No hepatic tissue is noted. A panel of immunostains was performed (see table below).

ANTIBODY	RESULT
Hepatocyte (HepPar1)	Negative
Arginase 1	Very focal positive (5%)
MOC31	Positive
Glipican-3	Positive
AFP	Positive
SALL4	Positive
pCEA	Positive for glandular pattern (no definitive canalicular pattern)
CDX2	Positive

ICD-0-3

adenocarcinoma, hepatoid
8576/3

Site: gastroesophageal
junction C16.0

hw
2/22/15

ICD-10: gastroesophageal
junction C16.0

Abdominal CT scan report indicates the presence of multiple hepatic masses without mention of tumor elsewhere in the abdomen. The laboratory information system indicates that the patient has a serum alpha-fetoprotein of 18,803ng/ml. The histologic and immunophenotypic features of this case are those of a hepatoid adenocarcinoma, considered a histologic subset of AFP producing carcinomas. These tumors frequently are associated with an elevated (often strikingly so) serum AFP. Most commonly they arise in the stomach where typically they are also associated with a superficial component of usual adenocarcinoma. They frequently metastasize to the liver and occasionally present as hepatic malignancy. Hepatoid adenocarcinomas may also arise at other

Source: NCI Genomic Data Commons file 4b567e08-e1eb-4e36-a000-03338aac6d51 (ER0018 ER-ABDN Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).